Somatic mutation profile of tumor specimen ALCH-B0AH-TTP1-A (aliquot ALCH-B0AH-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0AH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.3 years (23,125 days).
Specimen ALCH-B0AH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46c23910-f8a7-42af-8ae9-1f980709a6f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AH-NB1-A (Blood Derived Normal), aliquot ALCH-B0AH-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9339e99d-1f8e-4a43-944f-4e531ffa43ab

The open-access MAF lists 258 somatic variants for this specimen: 167 protein-altering or splice-affecting, 55 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 55, Intron 18, Nonsense Mutation 11, 3'UTR 6, 5'Flank 4, 5'UTR 4, RNA 3, Splice Site 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 75/430 reads (17%) | catalogued as rs1131691994, CD1415194, CM143426, CM143427, COSV62217195, COSV62228810; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 66/850 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1554826026, COSV64290565; ClinVar: uncertain significance; called by muse, mutect2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 71/425 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771662441, COSV61254693; called by muse, mutect2, varscan2
- AGAP2 | c.3025C>A p.R1009S (on ENST00000547588 / NM_001122772.2; = p.R653S on NM_014770.4) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1432619645, COSV57728143; called by muse, mutect2, varscan2
- AIM2 | c.699C>A p.D233E | Missense Mutation (SNP) | VAF 83/623 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as rs1284568832; called by muse, mutect2, varscan2
- ATP9A | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100124509, COSV58762928; called by muse, mutect2, varscan2
- C8orf34 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (1); catalogued as rs989471122; called by muse, mutect2, varscan2
- CENPJ | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 106/888 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV67883427; called by muse, mutect2, varscan2
- CFAP44 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 34/474 reads (7%) | catalogued as COSV57662984; called by muse, mutect2
- CIB4 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56602573; called by muse, mutect2, varscan2
- CLTCL1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1555951472, COSV54230412; called by muse, mutect2, varscan2
- CLUH | c.3346G>A p.G1116R (on ENST00000435359; = p.G1155R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101425741, COSV70928113; called by muse, mutect2, varscan2
- CNGB1 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs766474948; called by muse, mutect2, varscan2
- COL11A1 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 52/652 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62172068; called by muse, mutect2
- COLEC12 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 31/335 reads (9%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.77); catalogued as COSV68370009, COSV68371006; called by muse, mutect2
- CSRNP3 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 32/542 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs543669496, COSV58775683; called by muse, mutect2
- CST9 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 63/542 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs374258117; called by muse, mutect2, varscan2
- DACH2 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV64182323; called by mutect2, varscan2
- DCAF4L2 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100151132; called by muse, mutect2
- DCSTAMP | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 31/341 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV52579798, COSV52580670; called by muse, mutect2
- DNAH5 | c.12223A>G p.M4075V | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1423192314; called by muse, mutect2, varscan2
- DZIP1L | c.1949G>T p.W650L | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1225458100; called by muse, mutect2
- EYS | c.9265G>A p.E3089K (on ENST00000370621 / NM_001292009.1; = p.E3068K on NM_001142800.2) | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1241787129, CM140604, COSV65485453; called by muse, mutect2
- FUT7 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs577588991, COSV99688560; called by muse, mutect2
- GABRG3 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61519216; called by muse, mutect2
- GRM1 | c.2555C>T p.T852I | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51308827; called by muse, mutect2
- HYDIN | c.15235G>T p.V5079F | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1322548532; called by muse, mutect2
- IGHG1 | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 42/417 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs780428467; called by muse, mutect2, varscan2
- IGSF22 | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375519590; called by muse, mutect2, varscan2
- KLKB1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52997949; called by muse, mutect2
- KRT2 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 25/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs568144185; called by muse, mutect2
- LPIN3 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1477945241; called by muse, mutect2, varscan2
- LRRTM4 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 44/694 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69140795; called by muse, mutect2
- MPP2 | c.667G>C p.A223P (on ENST00000461854 / NM_001278372.2; = p.A199P on NM_005374.5) | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.587); catalogued as COSV52235929; called by muse, mutect2, varscan2
- MYH7 | c.5803G>A p.E1935K | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs907589577, COSV62525526; called by muse, mutect2
- NBN | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 97/647 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV55375249; called by muse, mutect2, varscan2
- NKX2-5 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61299394; called by muse, varscan2
- NPAT | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 68/786 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV53717289; called by muse, mutect2
- OR4P4 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs771370241, COSV100111638; called by muse, mutect2, varscan2
- OR9Q2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV61111904; called by muse, mutect2
- PAK5 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100781450; called by muse, mutect2, varscan2
- PAPSS1 | c.1001G>C p.R334P | Missense Mutation (SNP) | VAF 57/493 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.772); catalogued as rs752110118; called by muse, mutect2, varscan2
- PDGFRA | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 64/661 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV57273348; called by muse, mutect2
- PLEKHA6 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766585194, COSV99692160; called by muse, mutect2
- PON3 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 53/920 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as COSV55699690, COSV99672549; called by muse, mutect2
- PRKCQ | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs764984890, COSV54108985; called by muse, mutect2
- SCN2A | c.955T>C p.Y319H | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs931327558; called by muse, mutect2
- SCN3A | c.3078C>A p.F1026L | Missense Mutation (SNP) | VAF 38/630 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV51810150; called by muse, mutect2
- SHANK2 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782270184; called by muse, mutect2
- SIM1 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as CM139284; called by muse, mutect2
- SLC18A3 | c.738G>T p.L246F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60327614; called by muse, mutect2
- SLC20A2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768856025; called by muse, mutect2, varscan2
- SLC2A12 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs147475994; called by muse, mutect2
- SLC8B1 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs867387566; called by muse, mutect2, varscan2
- SPHKAP | c.2444C>A p.S815* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as COSV60869530; called by muse, mutect2, varscan2
- TAS2R16 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.065); catalogued as rs1207059482, COSV50797227; called by muse, mutect2, varscan2
- TBX15 | c.974C>A p.P325H (on ENST00000369429 / NM_001330677.2; = p.P219H on NM_152380.3) | Missense Mutation (SNP) | VAF 82/818 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1250486685; called by muse, mutect2
- TENM4 | c.4147G>T p.G1383C | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53616337; called by muse, mutect2
- TEX11 | c.1042C>T p.H348Y (on ENST00000344304; = p.H333Y on NM_031276.3) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV60229892; called by muse, varscan2
- TRPS1 | c.2372A>G p.N791S (on ENST00000220888 / NM_001330599.2; = p.N804S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/663 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs761148536; called by muse, mutect2
- TSC2 | c.5035G>T p.E1679* | Nonsense Mutation (SNP) | VAF 38/226 reads (17%) | catalogued as COSV99237033; called by muse, mutect2, varscan2
- UHRF1BP1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368358653; called by muse, mutect2
- USH2A | c.6662G>C p.C2221S | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56409265; called by muse, mutect2
- USH2A | c.5480G>T p.G1827V | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV56410708; called by muse, mutect2
- VPS13B | c.3314A>G p.H1105R | Missense Mutation (SNP) | VAF 134/856 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs769237316; called by muse, mutect2, varscan2
- VPS13B | c.6181G>T p.D2061Y | Missense Mutation (SNP) | VAF 50/485 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs775482916, COSV62140608; called by muse, mutect2, varscan2
- ZC3H11A | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV59746277; called by muse, mutect2, varscan2
- ZDBF2 | c.1922G>A p.R641K | Missense Mutation (SNP) | VAF 67/628 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV65629096; called by muse, mutect2, varscan2
- ZNF337 | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 45/543 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV53323266; called by muse, mutect2
- ABL2 | c.1788A>T p.Q596H (on ENST00000502732 / NM_007314.4; = p.Q581H on NM_005158.5) | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2
- ADAMTS6 | c.2687C>A p.T896N | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTSL3 | c.2835G>C p.Q945H | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ALG6 | c.235C>G p.H79D | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AMER2 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2
- ANK2 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 42/593 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANKRD20A4P | c.1139A>C p.K380T | Missense Mutation (SNP) | VAF 41/617 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- ARPP21 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASCC3 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 25/571 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- AXDND1 | c.1472G>A p.W491* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- BICC1 | c.2702T>C p.L901P | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC5 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 18/276 reads (7%) | called by muse, mutect2
- BUD13 | c.237+1G>T p.X79_splice | Splice Site (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- C4orf54 | c.3587G>T p.R1196M | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CCDC57 | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CCNE1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCNT2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CDKN2D | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP54 | c.9100A>G p.M3034V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- CNTN2 | c.2853C>A p.Y951* | Nonsense Mutation (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- CNTNAP5 | c.1204G>C p.G402R | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL21A1 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 47/555 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- COL5A3 | c.5194C>A p.Q1732K | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- COMMD10 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CUBN | c.9935C>G p.S3312C | Missense Mutation (SNP) | VAF 33/593 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2
- CYP27B1 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CYP2C9 | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- DAO | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 48/676 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- DISC1 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DNAH7 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- DNMBP | c.3527A>G p.Q1176R | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.082); called by muse, mutect2
- DTNB | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DZIP1L | c.1950G>T p.W650C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ECM1 | c.1435A>T p.I479F | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1A2 | c.21C>A p.H7Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EIF5B | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.287); called by muse, mutect2
- EPHA8 | c.1088A>C p.N363T | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- FAM131B | c.494G>T p.S165I | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- FREM3 | c.4840G>T p.E1614* | Nonsense Mutation (SNP) | VAF 34/372 reads (9%) | called by muse, mutect2
- GABRA5 | c.1246A>T p.K416* | Nonsense Mutation (SNP) | VAF 59/804 reads (7%) | called by muse, mutect2
- GABRB3 | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 32/457 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2
- GJC3 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 23/590 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.211); called by muse, mutect2
- GNAS | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 58/742 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- H6PD | c.1449G>A p.W483* | Nonsense Mutation (SNP) | VAF 63/567 reads (11%) | called by muse, mutect2, varscan2
- HEATR5A | c.5065C>G p.L1689V | Missense Mutation (SNP) | VAF 80/642 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- HMG20B | c.380A>C p.K127T | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- IGKV1-6 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 44/519 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2
- KCNQ2 | c.1606C>A p.L536I (on ENST00000359125 / NM_172107.4; = p.L508I on NM_004518.6) | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA2012 | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 76/630 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- KMT2A | c.9052A>T p.N3018Y | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KRTAP10-9 | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KTI12 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMB4 | c.4587G>T p.M1529I | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- LRRK2 | c.3589C>A p.H1197N | Missense Mutation (SNP) | VAF 29/419 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2
- MAFA | c.70T>A p.F24I | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2
- MAP4K1 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP4K3 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- MKI67 | c.3337G>C p.G1113R | Missense Mutation (SNP) | VAF 55/489 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MSX2 | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP1 | c.1652G>A p.C551Y | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NLRP8 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 21/586 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2
- OR1S2 | c.455G>T p.R152M | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR2M2 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T4 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 48/489 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- OR52R1 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OR5D13 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCYT1A | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 25/436 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2
- PDGFRA | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 65/661 reads (10%) | called by muse, mutect2
- PIWIL2 | c.2614A>C p.T872P | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD1 | c.9389G>T p.R3130L | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PKN3 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- PLAA | c.1492G>T p.G498C | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PPT2 | c.317A>T p.H106L | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PTPN4 | c.1515+1G>T p.X505_splice | Splice Site (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- RBMXL3 | c.981C>G p.C327W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); called by muse, mutect2
- REG1A | c.370T>C p.W124R | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RELN | c.3211T>A p.S1071T | Missense Mutation (SNP) | VAF 114/763 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SCN3A | c.3079C>A p.Q1027K | Missense Mutation (SNP) | VAF 39/640 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.11); called by muse, mutect2
- SEC23IP | c.2358C>G p.F786L | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); called by muse, mutect2
- SEMA6B | c.574T>A p.F192I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC22A3 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 60/815 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC9C2 | c.2313+2T>G p.X771_splice | Splice Site (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- SOGA1 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX13 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.092); called by muse, mutect2
- SPPL2C | c.496C>A p.R166S | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SRP54 | c.1212A>T p.Q404H | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ST6GAL2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 15/174 reads (9%) | PolyPhen benign (0.007); called by muse, mutect2
- TAF3 | c.1793T>G p.V598G | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- TAT | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 81/655 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TG | c.3410C>T p.P1137L | Missense Mutation (SNP) | VAF 71/425 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TLL2 | c.2557A>T p.S853C | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- VKORC1L1 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); called by muse, mutect2
- ZAR1L | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- ZBTB38 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 48/775 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- ZBTB38 | c.1713G>C p.M571I | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF732 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- ABCA13 | c.4746C>T p.A1582= | Silent (SNP) | VAF 27/184 reads (15%) | called by muse, mutect2, varscan2
- ACER1 | c.516G>C p.L172= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as COSV56835047; called by muse, mutect2
- AHNAK | c.4083G>T p.G1361= | Silent (SNP) | VAF 43/650 reads (7%) | called by muse, mutect2
- AHR | c.1566A>G p.S522= | Silent (SNP) | VAF 34/572 reads (6%) | catalogued as rs1292932860; called by muse, mutect2
- AIPL1 | c.369G>T p.L123= | Silent (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- AKAP13 | c.7126T>C p.L2376= (on ENST00000394518 / NM_007200.5; = p.L2380= on NM_006738.6) | Silent (SNP) | VAF 14/195 reads (7%) | catalogued as rs1297409650; called by muse, mutect2
- ATP9A | c.868C>A p.R290= | Silent (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2, varscan2
- CADPS | c.1170C>A p.S390= | Silent (SNP) | VAF 41/252 reads (16%) | catalogued as COSV51892249; called by muse, mutect2, varscan2
- CAPN10 | c.1383C>G p.L461= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs768985963; called by muse, mutect2, varscan2
- CCDC197 | c.9C>G p.A3= | Silent (SNP) | VAF 20/243 reads (8%) | called by muse, mutect2
- CDH13 | c.687G>C p.V229= | Silent (SNP) | VAF 28/394 reads (7%) | catalogued as COSV51800140; called by muse, mutect2
- CENATAC | c.441G>C p.V147= | Silent (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- COL4A2 | c.4119G>A p.K1373= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- DCDC1 | c.1635A>C p.P545= | Silent (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- DNAAF3 | c.1512T>C p.C504= (on ENST00000524407 / NM_001256715.2; = p.C551= on NM_178837.4) | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- ERCC6 | c.217C>T p.L73= | Silent (SNP) | VAF 22/225 reads (10%) | called by muse, mutect2
- ERICH3 | c.357C>T p.I119= | Silent (SNP) | VAF 46/417 reads (11%) | called by muse, varscan2
- EYS | c.1278C>T p.F426= | Silent (SNP) | VAF 29/551 reads (5%) | called by muse, mutect2
- FAT1 | c.1533G>A p.A511= | Silent (SNP) | VAF 34/448 reads (8%) | catalogued as rs370872618; called by muse, mutect2
- GABRB3 | c.1041C>A p.A347= | Silent (SNP) | VAF 34/466 reads (7%) | called by muse, mutect2
- GALNT14 | c.783C>T p.S261= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV61105162; called by muse, mutect2, varscan2
- GALNT17 | c.1734C>T p.G578= | Silent (SNP) | VAF 31/374 reads (8%) | called by muse, mutect2
- GCM2 | c.1263T>A p.T421= | Silent (SNP) | VAF 34/502 reads (7%) | called by muse, mutect2
- GFI1 | c.384G>A p.A128= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- H1-5 | c.594G>A p.P198= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as COSV58898866; called by muse, mutect2
- IGSF10 | c.2259A>G p.P753= | Silent (SNP) | VAF 30/575 reads (5%) | catalogued as rs1450587198; called by muse, mutect2
- KANK4 | c.936C>T p.P312= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as rs778849688; called by muse, mutect2
- KCNC3 | c.1167C>T p.I389= | Silent (SNP) | VAF 40/572 reads (7%) | catalogued as COSV100979262; called by muse, mutect2
- KNG1 | c.570G>T p.V190= | Silent (SNP) | VAF 33/558 reads (6%) | called by muse, mutect2
- MARCO | c.801A>T p.A267= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- MCF2L2 | c.3288G>T p.A1096= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- MUC2 | c.18C>A p.A6= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- MYH8 | c.4251T>G p.L1417= | Silent (SNP) | VAF 39/360 reads (11%) | called by muse, mutect2, varscan2
- MYNN | c.918A>T p.T306= | Silent (SNP) | VAF 40/672 reads (6%) | called by muse, mutect2
- NECTIN4 | c.258C>T p.Y86= | Silent (SNP) | VAF 25/251 reads (10%) | catalogued as rs1461364544, COSV63512252; called by muse, mutect2
- NELL2 | c.2409C>T p.H803= | Silent (SNP) | VAF 81/568 reads (14%) | called by muse, mutect2, varscan2
- NELL2 | c.573A>G p.L191= | Silent (SNP) | VAF 56/543 reads (10%) | called by muse, mutect2, varscan2
- NIM1K | c.930C>T p.P310= | Silent (SNP) | VAF 21/278 reads (8%) | catalogued as rs748796456; called by muse, mutect2
- NOBOX | c.1857A>T p.P619= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs1392582908; called by muse, mutect2, varscan2
- OR11L1 | c.762C>A p.T254= | Silent (SNP) | VAF 36/406 reads (9%) | catalogued as COSV100869502; called by muse, mutect2
- OR5H1 | c.636G>T p.V212= | Silent (SNP) | VAF 51/788 reads (6%) | catalogued as COSV100641808; called by muse, mutect2
- OR5H14 | c.60A>G p.Q20= | Silent (SNP) | VAF 22/388 reads (6%) | catalogued as COSV71193649; called by muse, mutect2
- PCDHB11 | c.576C>T p.P192= | Silent (SNP) | VAF 39/390 reads (10%) | catalogued as rs1420340953; called by muse, mutect2, varscan2
- PCDHB9 | c.975A>T p.G325= | Silent (SNP) | VAF 34/449 reads (8%) | called by muse, mutect2
- PGBD1 | c.762C>G p.L254= | Silent (SNP) | VAF 22/283 reads (8%) | called by muse, mutect2
- PRCD | c.157C>T p.L53= | Silent (SNP) | VAF 108/467 reads (23%) | catalogued as COSV53150221; called by muse, mutect2, varscan2
- QSER1 | c.1626A>G p.P542= (on ENST00000399302; = p.P671= on NM_001076786.3) | Silent (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- SI | c.1614C>A p.L538= | Silent (SNP) | VAF 30/406 reads (7%) | catalogued as COSV52266320; called by muse, mutect2
- STXBP5L | c.733C>T p.L245= | Silent (SNP) | VAF 19/304 reads (6%) | called by muse, mutect2
- TMTC1 | c.2154G>A p.E718= (on ENST00000539277 / NM_001193451.2; = p.E610= on NM_175861.3) | Silent (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- TNXB | c.2595T>A p.A865= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- TRIM38 | c.570A>T p.L190= | Silent (SNP) | VAF 21/510 reads (4%) | called by muse, mutect2
- TSPAN9 | c.264C>T p.I88= | Silent (SNP) | VAF 25/367 reads (7%) | catalogued as rs571507809; called by muse, mutect2
- ZNF423 | c.3384C>G p.L1128= (on ENST00000563137 / NM_001379286.1; = p.L1120= on NM_015069.4) | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- ZNF460 | c.690G>A p.G230= | Silent (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- AL121758.1 | c.*624G>C | 3'UTR (SNP) | VAF 16/438 reads (4%) | catalogued as COSV67937909; called by muse, mutect2
- ART3 | c.1004-10T>C | Intron (SNP) | VAF 21/242 reads (9%) | catalogued as rs767429708; called by muse, mutect2
- ASB5 | c.197-16176G>T | Intron (SNP) | VAF 33/374 reads (9%) | called by muse, mutect2
- ASTN2 | c.3782+3072G>T | Intron (SNP) | VAF 24/377 reads (6%) | called by muse, mutect2
- ATP8A2 | c.3184-34360G>T | Intron (SNP) | VAF 30/343 reads (9%) | called by muse, mutect2
- BIRC8 | n.1202G>A | RNA (SNP) | VAF 52/373 reads (14%) | called by muse, mutect2, varscan2
- BOLL | c.*43C>A | 3'UTR (SNP) | VAF 28/482 reads (6%) | catalogued as COSV99987334; called by muse, mutect2
- C10orf90 | c.1243+1137G>T | Intron (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2, varscan2
- DIO2 | c.223-2380C>G | Intron (SNP) | VAF 29/355 reads (8%) | called by muse, mutect2
- GABRG3 | c.271-55260G>A | Intron (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- GLYCTK | c.*1883C>T | 3'UTR (SNP) | VAF 34/186 reads (18%) | catalogued as rs1349434322; called by muse, mutect2, varscan2
- GUSB | c.-26G>T | 5'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- HHLA1 | c.1469+1016_1469+1020del | Intron (DEL) | VAF 57/330 reads (17%) | catalogued as rs918653147; called by pindel, varscan2
- HNF1B | c.1045+149dup | Intron (INS) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- HSPB7 | chr1:16019446 G>C | 5'Flank (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- MIR876 | n.60C>A | RNA (SNP) | VAF 92/309 reads (30%) | called by muse, mutect2, varscan2
- MON2 | chr12:62603309 T>C | 3'Flank (SNP) | VAF 4/37 reads (11%) | catalogued as rs1230850442; called by muse, mutect2, varscan2
- MYLK | c.3652+82C>T | Intron (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- NBPF7 | n.914C>A | RNA (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- NDUFAF5 | c.*1000G>T | 3'UTR (SNP) | VAF 40/349 reads (11%) | called by muse, mutect2, varscan2
- NDUFV3 | c.-20G>T | 5'UTR (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- NEK7 | c.198+3220G>A | Intron (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- NEU3 | c.307-1102G>T | Intron (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- OTUD6B | c.316-1722G>C | Intron (SNP) | VAF 89/624 reads (14%) | called by muse, mutect2, varscan2
- PPARG | c.-45C>G | 5'UTR (SNP) | VAF 78/405 reads (19%) | called by muse, mutect2, varscan2
- PSME1 | c.-48C>T | 5'UTR (SNP) | VAF 16/105 reads (15%) | catalogued as rs1288585500; called by muse, mutect2, varscan2
- PUM1 | chr1:31065707 G>A | 5'Flank (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- RALGDS | c.*46G>T | 3'UTR (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809939 C>A | 5'Flank (SNP) | VAF 48/444 reads (11%) | called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809940 T>A | 5'Flank (SNP) | VAF 50/440 reads (11%) | called by muse, mutect2, varscan2
- SHC1 | c.1624-242C>G | Intron (SNP) | VAF 92/595 reads (15%) | catalogued as COSV63534800; called by muse, varscan2
- SMPX | c.*196A>T | 3'UTR (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- SPICE1 | c.2323+24A>G | Intron (SNP) | VAF 22/314 reads (7%) | catalogued as rs770024627; called by muse, mutect2
- SYNE1 | c.10145+1093A>G | Intron (SNP) | VAF 22/365 reads (6%) | catalogued as rs1364372383; called by muse, mutect2
- SYS1 | c.163-111A>G | Intron (SNP) | VAF 48/374 reads (13%) | called by muse, mutect2, varscan2
- ZC3H14 | c.2006-20C>G | Intron (SNP) | VAF 60/738 reads (8%) | called by muse, mutect2
